Gene-level copy-number profile of tumor specimen C3L-06316-04 from CPTAC case C3L-06316, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.7 years (23,986 days).
Specimen C3L-06316-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a5244cac-3baa-4735-b7be-d0a5505bc73a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06316-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/0b81a1b7-5633-49d1-87c1-ceae7825f3b3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 1,199; copy number 2: 17,153; copy number 3: 27,925; copy number 4: 12,052; copy number 5: 30; copy number 6: 24; copy number 7: 14.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,803,784, 3 genes (within-gene range 0–3): RPS26P3, RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:42,185,339–42,185,791, 1 gene, copy number 7: IGKV1OR10-1.
- chr11:89,498,748–89,734,782, 13 genes, copy number 7: H3P34, AP003400.4, AP003400.5, AP003400.1, AP003400.2, AP003400.3, AP003400.6, FOLH1B, UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5.

Autosomal genes at a single copy (total copy number 1): 1,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
